Somatic mutation profile of tumor specimen ALCH-B2LK-TTP1-A (aliquot ALCH-B2LK-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2LK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 70.9 years (25,900 days).
Specimen ALCH-B2LK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee2fcc83-445e-4c71-bb2d-43a953678767.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2LK-NB1-A (Blood Derived Normal), aliquot ALCH-B2LK-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b641b9a6-63c3-406a-a691-eef5241bc4cd

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 71/525 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 66/265 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.2936T>A p.M979K | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54389021; called by muse, mutect2, varscan2
- ARHGEF18 | c.1730G>A p.R577Q (on ENST00000359920 / NM_001130955.2; = p.R473Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs754731608; called by muse, mutect2, varscan2
- CD22 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs575288611, COSV99323215; called by muse, mutect2, varscan2
- COL16A1 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54704507; called by muse, mutect2, varscan2
- CSMD2 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as rs1391538564, COSV99584434; called by muse, mutect2
- FLI1 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs201425969; called by muse, mutect2, varscan2
- MEGF8 | c.7876G>A p.G2626S (on ENST00000251268 / NM_001271938.2; = p.G2559S on NM_001410.3) | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200506642; called by muse, mutect2, varscan2
- MIER3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394004595; called by muse, mutect2, varscan2
- SIRT6 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs201495361; called by mutect2, varscan2
- TRIM75P | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 49/173 reads (28%) | catalogued as COSV72295794; called by muse, mutect2, varscan2
- WIPF3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs374540847; called by muse, mutect2, varscan2
- WNT10A | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1228372182; called by muse, mutect2
- ZNF716 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as rs1280274237; called by muse, mutect2
- ATF7IP | c.3241A>T p.M1081L | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EME2 | c.172A>G p.R58G | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXO4 | c.637A>T p.K213* | Nonsense Mutation (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2, varscan2
- HS3ST5 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2
- IRS2 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- LRRC32 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.634); called by muse, mutect2
- NKX1-1 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLGN3 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.057); called by muse, varscan2
- SMPX | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 64/558 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ABCB11 | c.3321G>A p.Q1107= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV55593377; called by mutect2, varscan2
- CD151 | c.21G>A p.K7= | Silent (SNP) | VAF 30/554 reads (5%) | called by muse, mutect2
- FBXL5 | c.2016C>T p.T672= | Silent (SNP) | VAF 67/331 reads (20%) | catalogued as rs760438641, COSV100378128; called by muse, mutect2, varscan2
- HIPK2 | c.2931C>T p.S977= | Silent (SNP) | VAF 66/242 reads (27%) | catalogued as rs528774935; called by muse, mutect2, varscan2
- HS3ST5 | c.789G>A p.L263= | Silent (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- KRTAP11-1 | c.375C>T p.G125= | Silent (SNP) | VAF 111/410 reads (27%) | catalogued as rs143272687; called by muse, mutect2, varscan2
- MUC5B | c.234C>T p.S78= | Silent (SNP) | VAF 203/298 reads (68%) | called by muse, mutect2, varscan2
- APOLD1 | c.96+257dup | Intron (INS) | VAF 14/131 reads (11%) | called by mutect2, pindel, varscan2
- CDHR5 | c.262-24C>T | Intron (SNP) | VAF 31/257 reads (12%) | catalogued as rs1419351246; called by muse, mutect2, varscan2
